Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RB, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RB-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] F Date of Receipt: [REDACTED]
Physi: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

1) Thyroid goiter, 2) anterior mediastinal tumor (separate).

Specimens Submitted:

- 1: Pre laryngeal nodule (fs)
- 2: Total thyroidectomy
- 3: Thymic mass (fs)
- 4: Left lobe of thymus

DIAGNOSIS:

1. "Nodule", prelaryngeal, biopsy:
- Thyroid tissue with nodular hyperplasia
2. Thyroid, total thyroidectomy:
- Nodular hyperplasia
- Changes consistent with FNA site are noted
3. Thymus, "mass", resection:
- Thymoma, WHO type B1, 5 cm in greatest dimension
- The tumor is encapsulated
- Margins are free of tumor
- Involuting thymus
- AE1/AE3 is confirmatory (see note)
4. Thymus, left lobe, resection:
- Involuting thymus

Note: Parts 3 and 4 have been seen in consultation with Dr. [REDACTED] who concurs with the diagnosis.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

ICD6-3

Thymoma, type B1 NOS
8581/1

Site: Thymus @ 37.9

Q103/12/141

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Physician:

Service:

Date of Report:

Page 2 of 4

1.) The specimen is received fresh for frozen section, labeled "Pre-laryngeal nodule" and consists of a tan nodule measuring 2.2 x 2 x 1.6 cm. The specimen is inked black and serially sectioned to reveal tan-pink, fleshy cut surfaces. A representative section is submitted for frozen section. The remainder of the specimen is entirely submitted.

Summary of sections:

FSC - frozen section control

RS - remaining specimen

2). The specimen is received fresh, labeled "Total thyroidectomy with substernal extension" and consists of a thyroid weighing 220 g. The right lobe measures 10x3.5x3.0 cm, the left lobe measures 9.5x5.0x4.0 cm and the isthmus measures 3x1x0.5 cm. There is a 3.0x2.5x1.5 cm protruding nodule at the posterior aspect of the left lobe. A 3x1.5x0.5 cm skeletal muscle is seen attached to the anterior surface of right lobe. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals multiple nodules in both left and right lobes ranging from 0.5 cm to 3.0 cm in greatest dimension. The nodules show gelatinous cut surface with focal hemorrhagic and cystic, yellowish greenish areas. The remaining thyroid parenchyma is red tan and beefy. There is a 2.0x1.5x0.5 cm lymph node-like nodule at the isthmus region. Representative sections of the specimen are submitted.

Summary of sections:

RL - right lobe

LL - left lobe

IS - isthmus

LN-bisected node-like nodule

3). The specimen is received fresh for frozen diagnosis and labeled with "thymic mass". It consists of a mass with attached fatty adipose tissue without orientation. The specimen measures 7x5.5x3.5 cm and is entirely inked with blue. Serial sectioning reveals a capsulated tumor measuring 5x3x3 cm. The tumor has red yellow tan variegated soft cut surface. The tumor does not invade the capsule and the surrounding adipose tissue grossly. The specimen is photographed and submitted to TPS. Representatively submitted.

Summary of sections:

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Date of Report:

Page 3 of 4

T-tumor

F-surrounding fat tissue

4.) The specimen is received in formalin, labeled "Left lobe of thymus" and consists of a unoriented, 16.0 g, 8.9 x 3.2 x 1.2 cm, lobular fragment of fatty tissue partially surrounded by a thin, focally hemorrhagic and fragmented, translucent sheath. The surface is inked in black and the specimen is sectioned to reveal focally hemorrhagic lobules of yellow adipose tissue separated by a thin band of tissue, devoid of a grossly identifiable lesion. Representative sections are submitted.

Summary of sections:

RS -- representative sections

Summary of Sections:

Part 1: Pre laryngeal nodule (fs)

Block	Sect.	Site	PCs
1		FSC	1
2		RS	2

Part 2: Total thyroidectomy

Block	Sect.	Site	PCs
1		IS	1
10		LL	10
1		LN	1
8		RL	8

Part 3: Thymic mass (fs)

Block	Sect.	Site	PCs
1		F	1
1		fsc	1
6		T	6

Part 4: Left lobe of thymus

Block	Sect.	Site	PCs
3		RS	6

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #

Physician:

Service:

Date of Report:

Page 4 of 4

1. Frozen section diagnosis: Pre laryngeal nodule (fs):
Well-differentiated follicular thyroid tissue
Permanent diagnosis: Same

3. Frozen section diagnosis: Thymic mass (fs): Thymoma
Permanent diagnosis: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Pre laryngeal nodule (fs):
Well-differentiated follicular thyroid tissue
Permanent diagnosis: Same

3. Frozen section diagnosis: Thymic mass (fs): Thymoma
Permanent diagnosis: Same

** End of Report **

stPAA Discrepancy		✓

Source: NCI Genomic Data Commons file 104e0beb-aeba-4a2b-b925-fcd000c5ede8 (TCGA-XM-A8RB.26C01AA5-473F-4ADB-9A15-8CCB1A7374D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).